Gene-level copy-number profile of tumor specimen TCGA-BR-8679-01A from TCGA case TCGA-BR-8679, project TCGA-STAD (Stomach Adenocarcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Fundus of stomach; AJCC pathologic stage: Stage IB; Tumor grade: G2; Age at diagnosis: 63.2 years (23,084 days).
Specimen TCGA-BR-8679-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-STAD.9f614e48-5446-4662-8ff3-3e244ec838e7.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-BR-8679-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 804 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/01fba68c-8f86-418b-8b98-6e51b7f5bc6b

Most common (modal) total copy number across autosomal genes: 3 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 0: 71; copy number 1: 6; copy number 2: 7,608; copy number 3: 22,891; copy number 4: 11,280; copy number 5: 8,489; copy number 6: 4,243; copy number 7: 2,533; copy number 8: 1,047; copy number 9: 1,530; copy number 11: 32; copy number 14: 22; copy number 16: 2; copy number 37: 11; copy number 42: 6; copy number 44: 7; copy number 48: 17; copy number 50: 24.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-BR-8679-01A-11D-2390-01): tumor purity 0.53, ploidy 3.65, whole-genome doublings 2.

Homozygous deletions (total copy number 0; autosomes only): 71 genes in 2 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr16:78,550,739–78,553,296, 1 gene: AC046158.3.
- chr21:10,328,411–15,065,936, 70 genes (within-gene range 0–2) (broad region; genes not listed).

Amplified relative to the modal value (total copy number ≥ 7, i.e. more than twice the modal value of 3; autosomes only): 5,231 genes in 10 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:202,911,812–248,919,946, 1,047 genes, copy number 8 (broad region; genes not listed).
- chr3:62,221,249–75,785,583, 182 genes, copy number 7–16 (broad region; genes not listed).
- chr3:75,964,980–75,965,069, 1 gene, copy number 9: Y_RNA.
- chr8:150,584–145,066,685, 2,481 genes, copy number 7 (broad region; genes not listed).
- chr12:24,704,503–25,250,936, 17 genes, copy number 48: AC023796.1, RN7SL38P, BCAT1, AC023796.2, AC026310.2, AC026310.1, BRI3P2, C12orf77, IRAG2, CENPUP2, AC023510.1, AC023510.2, CFAP94, ETFRF1, KRAS, AC092794.1, AC092794.2.
- chr12:55,193,882–55,322,364, 8 genes, copy number 7–44: OR10U1P, OR10A7, OR6C74, OR6C69P, OR6C72P, OR6C6, OR6C5P, OR6C1.
- chr12:71,439,798–71,667,725, 6 genes, copy number 42 (within-gene range 3–42): LGR5, AC090116.1, AC078860.3, AC078860.2, ZFC3H1, AC078860.1.
- chr12:96,160,692–97,761,859, 35 genes, copy number 37–50: LINC02452, ELK3, AC008149.1, AC008149.2, CDK17, RNU4-24P, AC125612.1, AC007513.1, RN7SKP11, CFAP54, EEF1A1P33, NEDD1, Y_RNA, AC007656.2, AC007656.1, AC007656.3, AC007656.4, LINC02409, RMST, MIR1251, AC007351.2, AC007351.3, AC007351.4, AC007351.1, AC018659.4, AC018659.3, AC018659.1, AC018659.7, AC018659.5, AC018659.8, MIR135A2, AC018659.6, AC018659.2, PAFAH1B2P2, RNU6-36P.
- chr20:87,250–16,053,197, 295 genes, copy number 9 (within-gene range 5–9) (broad region; genes not listed).
- chr20:16,177,933–64,313,132, 1,159 genes, copy number 9 (broad region; genes not listed).

Autosomal genes at a single copy (total copy number 1): 6. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
